FM case AD3770 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/5127f5cd-a792-4e16-bf5f-2ae02347c282

Male, 41.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; primary biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
